Surgical pathology report (de-identified scan), TCGA case TCGA-PR-A5PH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Roswell Park, specimen TCGA-PR-A5PH-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S): A. ADRENAL GLAND LEFT
B. LYMPH NODE PERIAORTIC

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Left adrenal tumor

ICDB-3
Pheochromocytoma, malignant
8700/13
Site: @ Adrenal Gland NOS
174.9
JW 2/1/13

GROSS DESCRIPTION:

A. ADRENAL GLAND LEFT

Received fresh is an adrenalectomy specimen measuring overall 14 x 11.5 x 4 cm and weighing 175 grams containing a tumor mass measuring 5.5 x 5 x 2.5 cm. The external surface is inked blue. The mass is encapsulated with brown-tan cut surface. A portion of normal golden yellow adrenal gland is seen measuring 3.5 x 3.5 x 1 cm. A portion of the specimen is submitted for tissue procurement. Gross photographs are taken. Representative sections are submitted in A1-A2-A9 (tumor) and A10-A11 (adrenal gland).

B. LYMPH NODE PERIAORTIC

Received in formalin is a fragment of beige-tan firm tissue measuring 0.7 x 0.6 x 0.5 cm. The entire specimen is submitted in cassette B1.

MICROSCOPIC DESCRIPTION:

Immunoperoxidase stains are performed on tissue sections from block# A2. The immunophenotypic features are in support of the diagnosis.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A2

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CHROMOGRANIN A	Positive	
SYNAPTOPHYSIN	Positive	
EMA	Negative	
CYTOKERATIN AE1/3	Negative	Rare tumor cells are positive
INHIBIN-ALPHA	Negative	
S-100	Negative	Sustentacular supporting cells are positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 2 of 2]
DIAGNOSIS:

A. ADRENAL GLAND, LEFT, ADRENALECTOMY:

- PHEOCHROMOCYTOMA. TUMOR SIZE 5.5 X 5 X 2.5 CM. MARGINS NEGATIVE FOR TUMOR. SEE NOTE

B. LYMPH NODE, PERIAORTIC, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1)

NOTE: The tumor is located 0.1 cm from closest inked margin. The tumor exhibits focal capsular invasion and extension into peri-adrenal adipose tissue. There is no definite evidence of vascular invasion, necrosis (only degenerative changes are seen), readily seen mitoses (none is seen), profound nuclear pleomorphism (random pleomorphism is seen), high cellularity, cellular monotony, or tumor cell spindling. Although the total histomorphologic score of this tumor, according to the reference below, is more seen in pheochromocytoma with benign clinical behavior, it is really still difficult to predict the clinical behavior of this tumor based merely on the histomorphology. Clinical and radiologic correlation is critical to exclude malignancy as strictly defined by documenting metastases in organs do not have normally chromaffin cells. See reference (*L. Thompson. Am J Surg Pathol 26(5): 551-556, 2002*).

Criteria	W 1/30/13	Yes	No

Source: NCI Genomic Data Commons file ec44a78e-ea64-4edc-9648-84dfd7b95364 (TCGA-PR-A5PH.F021F72D-C909-49CA-90FA-295B2EE9D3BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).